Somatic mutation profile of tumor specimen TCGA-CG-4443-01A (aliquot TCGA-CG-4443-01A-01D-1158-08) from TCGA case TCGA-CG-4443, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.4 years (24,990 days).
Specimen TCGA-CG-4443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfd9610b-98e2-47b7-953b-d56ac2c26752.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4443-10A (Blood Derived Normal), aliquot TCGA-CG-4443-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44e9a4dd-5383-4d59-8a99-74ee89b6a6e4

The open-access MAF lists 105 somatic variants for this specimen: 75 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 29, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.5074G>A p.D1692N | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs80187739, CM129092, CM165042, CS041877, CS128883, CS982090, COSV58787854; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.3688C>A p.L1230I | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51934196, COSV99346363; called by muse, mutect2, varscan2
- ADH1B | c.509T>G p.V170G | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59295911; called by muse, mutect2
- ALPP | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs148017705; called by muse, mutect2, varscan2
- ATP9A | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 68/549 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as COSV58765176; called by muse, mutect2, varscan2
- BEST3 | c.1422G>C p.E474D | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58300568; called by muse, mutect2, varscan2
- BORA | c.1081G>C p.E361Q (on ENST00000613797; = p.E286Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs753266386, COSV64695086; called by muse, mutect2, varscan2
- BRWD3 | c.4177G>T p.D1393Y | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64746597; called by muse, mutect2, varscan2
- BTBD11 | c.2399A>T p.Y800F (on ENST00000280758 / NM_001018072.2; = p.Y337F on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV55021724; called by muse, mutect2, varscan2
- C12orf40 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV61130034, COSV61131094; called by muse, mutect2, varscan2
- CACNA1C | c.3997G>A p.V1333I | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59709103; called by muse, mutect2, varscan2
- CDH12 | c.1763G>C p.R588P | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66397476; called by muse, mutect2, varscan2
- CDHR2 | c.3890G>A p.G1297E | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56137079; called by muse, mutect2, varscan2
- CERK | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53450832; called by muse, mutect2, varscan2
- CNNM2 | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.269); catalogued as COSV63997982; called by muse, mutect2, varscan2
- COL4A1 | c.2473A>G p.K825E | Missense Mutation (SNP) | VAF 154/250 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV65423852; called by muse, mutect2, varscan2
- DAAM1 | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.916); catalogued as COSV62835497; called by muse, mutect2, varscan2
- DIS3L2 | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553539253, COSV56052052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMTF1 | c.2039C>A p.S680Y | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV57538301; called by muse, mutect2, varscan2
- DNAH3 | c.8689G>A p.V2897M | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199565346, COSV54515005; called by muse, mutect2, varscan2
- EGFL7 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV58247397; called by muse, mutect2, varscan2
- FAM234B | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52194086; called by muse, mutect2, varscan2
- GAPVD1 | c.2254G>C p.D752H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV52922068; called by muse, mutect2, varscan2
- GOLGB1 | c.2609A>C p.Q870P | Missense Mutation (SNP) | VAF 187/385 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.897); catalogued as COSV61464149; called by muse, mutect2, varscan2
- HHATL | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55132418; called by muse, mutect2, varscan2
- HRG | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.497); catalogued as COSV51644861; called by muse, varscan2
- KDM5A | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV66991722; called by muse, mutect2, varscan2
- KDM5C | c.4489G>C p.E1497Q | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.027); catalogued as COSV64764256; called by muse, mutect2, varscan2
- KMT2D | c.5044G>T p.E1682* | Nonsense Mutation (SNP) | VAF 36/127 reads (28%) | catalogued as COSV56413178, COSV56427958; called by muse, mutect2, varscan2
- KRT82 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57785813; called by muse, mutect2, varscan2
- LIPN | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs747108736, COSV68383880; called by muse, mutect2, varscan2
- MMP16 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs199761222, COSV54159400; called by muse, mutect2, varscan2
- MUL1 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.726); catalogued as COSV51641405; called by muse, mutect2, varscan2
- NCKAP1L | c.119A>T p.K40I | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53205529; called by muse, mutect2, varscan2
- NDUFS6 | c.312C>G p.D104E | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs754258714, COSV56876411; called by muse, mutect2, varscan2
- NID1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV51618318; called by muse, mutect2, varscan2
- OBSCN | c.18096G>T p.K6032N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1239989627, COSV52761986; called by muse, mutect2, varscan2
- OR4C16 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 129/353 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV58941474; called by muse, mutect2, varscan2
- OR6K6 | c.1000T>A p.Y334N (on ENST00000368144; = p.Y310N on NM_001005184.1) | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV63743900; called by muse, mutect2, varscan2
- PDZD4 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV51246158; called by muse, mutect2, varscan2
- PKD1L1 | c.5999C>T p.T2000I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV56962441; called by muse, mutect2, varscan2
- PLEC | c.3095C>G p.A1032G (on ENST00000322810 / NM_201380.4; = p.A922G on NM_000445.5) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV59623870; called by muse, mutect2, varscan2
- PLOD2 | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV51463735; called by muse, mutect2, varscan2
- PTK6 | c.390G>C p.W130C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV53916432, COSV99037007; called by muse, mutect2
- RANBP2 | c.4387G>A p.D1463N | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV51699197; called by muse, mutect2, varscan2
- RGP1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV65239235; called by muse, mutect2, varscan2
- SAMHD1 | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV53429110; called by muse, mutect2, varscan2
- SCAP | c.1315G>C p.V439L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV55560495; called by muse, mutect2, varscan2
- SCUBE1 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100683646; called by muse, mutect2
- SEMA5A | c.2360G>C p.W787S | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66789571; called by muse, mutect2
- SETDB2 | c.1388A>G p.K463R | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs367576307; called by muse, mutect2
- SIT1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as COSV52399764; called by muse, mutect2, varscan2
- SLC22A9 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54166699; called by muse, mutect2, varscan2
- SLC43A3 | c.1038C>G p.Y346* | Nonsense Mutation (SNP) | VAF 39/339 reads (12%) | catalogued as COSV61450164; called by muse, mutect2, varscan2
- SLC6A11 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54392206; called by muse, mutect2
- SMARCC2 | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 171/213 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs939929481, COSV57216730; called by muse, mutect2, varscan2
- THNSL2 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV59082580; called by muse, mutect2, varscan2
- TP53TG5 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 91/885 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65577253; called by muse, mutect2, varscan2
- TRPC7 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.34); PolyPhen benign (0.149); catalogued as rs771143978, COSV61456542; called by muse, mutect2, varscan2
- TXNDC16 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55984138; called by muse, mutect2, varscan2
- VWF | c.8371G>T p.G2791C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54616642; called by muse, mutect2, varscan2
- ZBTB43 | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as COSV65094667, COSV65095267; called by muse, mutect2, varscan2
- ZER1 | c.790T>C p.F264L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52565126; called by muse, mutect2, varscan2
- ZFP64 | c.801G>C p.K267N | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53798012; called by muse, mutect2, varscan2
- ZNF571 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV60732857; called by muse, mutect2, varscan2
- ZNF831 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs763411148, COSV64039059; called by muse, mutect2
- ZNRF1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57727957; called by muse, mutect2, varscan2
- EPB41L2 | c.1661-5_1666delinsTTT p.X554_splice | Splice Site (DEL) | VAF 21/44 reads (48%) | called by pindel, varscan2*
- FOXD4L1 | c.19_31del p.E7Pfs*41 | Frame Shift Del (DEL) | VAF 60/191 reads (31%) | called by mutect2, pindel, varscan2
- GCKR | c.726_739del p.F243Cfs*32 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- LILRA6 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- PDE7A | c.818_827del p.T273Rfs*18 (on ENST00000401827 / NM_001242318.3; = p.T247Rfs*18 on NM_002603.4) | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- RELN | c.4188_4207del p.K1396Nfs*28 | Frame Shift Del (DEL) | VAF 31/54 reads (57%) | called by mutect2, pindel*, varscan2*
- SYT10 | c.152-1_154del p.X51_splice | Splice Site (DEL) | VAF 15/31 reads (48%) | called by mutect2, pindel, varscan2
- ZFAND4 | c.2175_*7del | Nonstop Mutation (DEL) | VAF 32/118 reads (27%) | called by pindel, varscan2
- ADGRF5 | c.3687C>A p.G1229= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as rs750705875, COSV99346365; called by muse, mutect2, varscan2
- ASH2L | c.384A>T p.T128= | Silent (SNP) | VAF 92/184 reads (50%) | catalogued as COSV51699176; called by muse, mutect2, varscan2
- ATP10D | c.1923G>A p.S641= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as rs779635673, COSV56706051; called by muse, mutect2, varscan2
- BATF2 | c.225G>A p.R75= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV57249769; called by muse, mutect2, varscan2
- CFAP251 | c.3432C>T p.S1144= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as rs746253460, COSV56609548; called by muse, mutect2, varscan2
- EDAR | c.1005C>T p.N335= | Silent (SNP) | VAF 52/127 reads (41%) | catalogued as rs776636635, COSV51501698, COSV51506841; called by muse, mutect2, varscan2
- FLT4 | c.240G>T p.V80= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV56104202; called by muse, mutect2, varscan2
- GPR78 | c.402G>A p.S134= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1300397634, COSV66762796; called by muse, mutect2, varscan2
- KIFC3 | c.1914C>G p.T638= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV65549796; called by muse, mutect2, varscan2
- KRTAP19-4 | c.69T>C p.Y23= | Silent (SNP) | VAF 70/180 reads (39%) | catalogued as COSV61858494; called by muse, mutect2, varscan2
- LATS1 | c.1509A>G p.V503= | Silent (SNP) | VAF 88/115 reads (77%) | catalogued as COSV53589101, COSV53593992; called by muse, mutect2, varscan2
- LYZL6 | c.408G>A p.R136= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs978403413; called by muse, mutect2, varscan2
- MYH6 | c.855C>T p.H285= | Silent (SNP) | VAF 162/366 reads (44%) | catalogued as rs895857373, COSV62449392; called by muse, mutect2, varscan2
- NUP133 | c.2262A>G p.E754= | Silent (SNP) | VAF 150/354 reads (42%) | catalogued as COSV54569943; called by muse, mutect2, varscan2
- PDXDC1 | c.564A>G p.Q188= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as rs762922596, COSV57905748; called by muse, mutect2, varscan2
- RTN1 | c.2028G>C p.T676= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV50721242, COSV99956557, COSV99957073; called by muse, mutect2, varscan2
- SEPTIN6 | c.960A>G p.L320= | Silent (SNP) | VAF 217/248 reads (88%) | catalogued as COSV59713429; called by muse, mutect2, varscan2
- SLC25A25 | c.108C>G p.L36= | Silent (SNP) | VAF 55/161 reads (34%) | catalogued as COSV66086000; called by muse, mutect2, varscan2
- TCERG1L | c.1611G>A p.T537= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs373129269; called by muse, mutect2, varscan2
- TCHH | c.4791C>T p.F1597= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as COSV64274040; called by muse, mutect2, varscan2
- TGM6 | c.2016C>T p.I672= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as COSV52478957, COSV52484711; called by muse, mutect2, varscan2
- TGM7 | c.903C>G p.S301= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV71772699, COSV71772883; called by muse, mutect2, varscan2
- TMEM102 | c.1077C>T p.C359= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV53439375; called by muse, mutect2, varscan2
- TOP2A | c.4281C>G p.T1427= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV68503022; called by muse, mutect2, varscan2
- TOR1AIP1 | c.429T>A p.S143= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV54869091; called by muse, varscan2
- TP63 | c.807G>A p.G269= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as COSV53202665; called by muse, mutect2, varscan2
- TUT4 | c.4803G>A p.L1601= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV57112317; called by muse, mutect2, varscan2
- UTP14A | c.228C>G p.V76= | Silent (SNP) | VAF 244/282 reads (87%) | catalogued as COSV64086631; called by muse, mutect2, varscan2
- ZNFX1 | c.4878C>T p.I1626= | Silent (SNP) | VAF 232/317 reads (73%) | catalogued as rs1568980383, COSV65596099; called by muse, varscan2
- PANK2 | c.1536+464C>T | Intron (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100262489; called by muse, mutect2, varscan2
